Gene-level copy-number profile of tumor specimen HCM-SANG-0292-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0292-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0292-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dae11266-e934-46e1-a9ec-502cf27f001b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0292-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/598d5eab-a165-4b98-894f-9fbab2a45123

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 588; copy number 1: 412; copy number 2: 7,864; copy number 3: 27,948; copy number 4: 12,193; copy number 5: 5,686; copy number 6: 2,813; copy number 7: 844; copy number 8: 323; copy number 10: 80; copy number 15: 105; copy number 39: 4; copy number 44: 14; copy number 59: 20; copy number 73: 20.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,192,657–30,421,108, 12 genes: MECR, AL590729.1, PTPRU, LINC01756, AL671862.1, AC092265.1, AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr6:156,776,020–157,210,779, 1 gene (within-gene range 0–3): ARID1B.
- chr6:156,779,678–157,119,706, 4 genes (within-gene range 0–3): MIR4466, AL355297.1, AL162578.1, AL049820.1.
- chr10:44,712–46,884, 1 gene: AL713922.1.
- chr11:56,576,736–56,629,860, 5 genes: OR5M10, OR5M13P, OR5M1, OR5AM1P, OR5M12P.
- chr21:13,038,160–14,658,821, 49 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1.
- chr21:16,754,519–16,873,691, 2 genes: AF130359.1, AF212831.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,410 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,919,082–177,610,330, 84 genes, copy number 8 (broad region; genes not listed).
- chr7:35,930,158–35,934,569, 2 genes, copy number 8: RNU6-1085P, AC087072.1.
- chr7:157,539,056–158,587,823, 1 gene, copy number 7 (within-gene range 6–7): PTPRN2.
- chr7:157,854,529–159,233,377, 17 genes, copy number 7: PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:63,651,457–64,383,787, 7 genes, copy number 7 (within-gene range 3–7): AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2.
- chr8:64,798,804–67,746,378, 52 genes, copy number 8–10: AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:76,966,768–77,014,028, 3 genes, copy number 7: MIR3149, PEX2, HIGD1AP18.
- chr8:79,259,402–81,924,348, 68 genes, copy number 7–10 (broad region; genes not listed).
- chr8:115,950,511–116,325,062, 1 gene, copy number 8 (within-gene range 3–8): LINC00536.
- chr8:116,289,622–128,564,679, 183 genes, copy number 8 (broad region; genes not listed).
- chr12:21,437,615–31,073,847, 163 genes, copy number 15–73 (within-gene range 5–73) (broad region; genes not listed).
- chr12:119,593,774–119,877,320, 6 genes, copy number 7 (within-gene range 4–7): TMEM233, RN7SKP197, PRKAB1, CIT, AC002563.1, MIR1178.
- chr12:123,289,109–123,598,582, 14 genes, copy number 8: SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2.
- chr20:2,453,010–18,467,281, 276 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:21,085,576–39,039,723, 432 genes, copy number 7 (broad region; genes not listed).
- chr20:48,921,711–53,875,557, 101 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 412. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
